CCDI case PBCCDY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/275fd75a-bdac-43e8-b718-f4c9c29aa80c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 22.7 years (8,287 days).

Biospecimens (3 samples)
- Sample 0DQ8WA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ8WX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ8YB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
